Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AANB, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AANB-01A (Primary Tumor).

[page 1 of 2]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

Document Type:

*Date - Date of Service:

Document Status:

Document Title:

Encounter info:

Contributor system:

* Final Report *

ORDERING PHYSICIAN:

Ordering Physician:

PRE-OPERATIVE DIAGNOSIS:

Right testicular mass

MICROSCOPIC DESCRIPTION:

Sections of the right testicular mass show predominantly embryonal carcinoma composed of neoplastic cells forming solid sheets and irregular clefts and spaces. The cells are medium to large and are polygonal with pleomorphic nuclei and prominent nucleoli. Mitotic activity is brisk and bizarre mitoses are frequent. Rare multinucleated cells are seen. Yolk sac tumor is present exhibiting a microcystic pattern and composed of medium to large cells with variable pleomorphism. Occasional eosinophilic intracytoplasmic globules are identified. Less than 1% of the tumor is composed of mature teratoma showing rare small patchy areas of well-developed glandular epithelium. Lymphovascular invasion is also identified (A6) and the rete testis is involved by tumor. The tumor is confined within the testis and does not extend through the tunica albuginea or involve the tunica vaginalis or epididymis. Sections of cord including the resection margin are free of malignancy.

Signature Line

Signed by:

ELECTRONIC SIGNATURE

*Mixed germ cell tumor
9085/3
Site R Testis NOS
C62.9
JN 03/1/14*

GROSS DESCRIPTION:

The specimen is received fresh from the O.R. and labelled "Right testicular mass". It consists of a right radical orchiectomy specimen. Overall, the specimen measures 15 x 5.5 x 3 cm and weighs 55 grams. The spermatic cord measures 11 cm in length by 1.2 cm in diameter and is grossly unremarkable. The testis itself measures 5.5 x 3.5 x 3 cm. The epididymis measures 6 cm in length by 0.5 x 0.6 cm. On sectioning, a relatively well-circumscribed but not encapsulated mass is identified, measuring 3.1 x 2.4 x 2.2 cm and located in the mid to lower pole of the testis. It extends to the tunica albuginea posteriorly and approaches the hilum. The tumor does not appear to penetrate the tunica albuginea or involve the tunica vaginalis. The mass itself is very firm and vaguely nodular, with variegated light and dark tan cut surfaces and areas of hemorrhage. Representative sections are submitted in a total of 11 cassettes with the tumor being totally embedded.

Printed by:

Printed on:

Page 1 of 2
(Continued)

[page 2 of 2]
HX SURGICAL PATHOLOGY REPORT

* Final Report *

SECTIONS:

A1-7: entire tumor
A8: uninvolved testis
A9: resection margin of spermatic cord
A10: mid portion of spermatic cord
A11: distal portion of spermatic cord

FINAL DIAGNOSIS:

RIGHT RADICAL ORCHIECTOMY:

RIGHT TESTICULAR MASS:

- MIXED GERM CELL TUMOR (EMBRYONAL CARCINOMA 90%, YOLK SAC TUMOR 9% AND MATURE TERATOMA 1%), 3.1 X 2.4 X 2.2 CM, CONFINED TO TESTIS
- LYMPHOVASCULAR SPACE INVASION IDENTIFIED
- TUMOR INVOLVING RETE TESTIS AND ABUTTING WITHOUT PENETRATING TUNICA ALBUGINEA
- EPIDIDYMIS AND SPERMATIC CORD WITH RESECTION MARGIN, FREE OF MALIGNANCY

Printed by:
Printed on:

Page 2 of 2
(End of Report)

Source: NCI Genomic Data Commons file 4b0e9c5e-d738-4ca6-9e41-57ac5af080ba (TCGA-XE-AANB-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).